Somatic mutation profile of tumor specimen MP2PRT-PAUZVL-TMP1-A (aliquot MP2PRT-PAUZVL-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUZVL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,541 days).
Specimen MP2PRT-PAUZVL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adf6fc12-6077-411d-a225-a14776a44deb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUZVL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUZVL-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3aa1308-b07f-41c9-923b-a3e3e4c6a6cb

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 29/237 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP3B2 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442353474, COSV55608425; called by muse, mutect2, varscan2
- CREBBP | c.3535A>G p.S1179G | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as CM1414686, COSV99062745; called by muse, mutect2, varscan2
- CYP11B2 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 71/584 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs970961565; called by muse, mutect2
- FLT3 | c.2517T>A p.D839E | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV54045931; called by muse, mutect2, varscan2
- KIFBP | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752833136, COSV62831808; called by muse, mutect2, varscan2
- NMUR2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs756384094, COSV54918385; called by muse, mutect2, varscan2
- OR5K2 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV71143125; called by muse, mutect2, varscan2
- PCSK6 | c.2811C>T p.N937= | Splice Region (SNP) | VAF 57/254 reads (22%) | catalogued as rs373791454; called by muse, mutect2, varscan2
- RARB | c.656G>A p.R219Q (on ENST00000383772 / NM_001290216.2; = p.R212Q on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1466673421; called by muse, mutect2
- APOBEC3B | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 91/175 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CCNA2 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CSMD3 | c.7674dup p.G2559Rfs*12 (on ENST00000297405 / NM_001363185.1; = p.G2455Rfs*12 on NM_052900.3) | Frame Shift Ins (INS) | VAF 58/201 reads (29%) | called by mutect2, pindel, varscan2
- H3C7 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 63/439 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HOMER2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 103/191 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NXPE4 | c.1394G>A p.S465N (on ENST00000375478 / NM_001077639.2; = p.S181N on NM_017678.3) | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS18 | c.58A>C p.T20P | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AK8 | c.474C>T p.P158= | Silent (SNP) | VAF 102/216 reads (47%) | called by muse, mutect2, varscan2
- MYO15B | c.6519G>A p.P2173= | Silent (SNP) | VAF 212/651 reads (33%) | catalogued as rs935113549, COSV73824763; called by muse, mutect2, varscan2
- RAC3 | c.366C>T p.D122= | Silent (SNP) | VAF 61/648 reads (9%) | called by muse, mutect2
